Somatic mutation profile of tumor specimen TCGA-VS-A9UV-01A (aliquot TCGA-VS-A9UV-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 74.9 years (27,348 days).
Specimen TCGA-VS-A9UV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 072138e5-7fe1-4745-9144-3887f43b5c04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UV-10A (Blood Derived Normal), aliquot TCGA-VS-A9UV-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0fb54a-1f2a-44ac-a4fc-3951394e062c

The open-access MAF lists 90 somatic variants for this specimen: 63 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 23, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, Intron 1, RNA 1, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 60/141 reads (43%) | catalogued as rs397508009, CM1110640, COSV101204561; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COQ4 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs773943371, COSV100306779; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ABCA12 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99791367; called by muse, mutect2, varscan2
- ADAMTS18 | c.2879A>G p.Q960R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs770997759, COSV99273751; called by muse, mutect2, varscan2
- AGPS | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99931612; called by muse, mutect2, varscan2
- AHNAK | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 86/97 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57219475; called by muse, mutect2, varscan2
- ARHGAP31 | c.3239C>T p.S1080L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs758554437, COSV51788690; called by muse, mutect2, varscan2
- ARHGAP5 | c.112T>C p.C38R | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565624; called by muse, mutect2, varscan2
- ASPH | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200072789; called by muse, mutect2, varscan2
- C2CD6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV99634112; called by muse, mutect2, varscan2
- CCDC88C | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1567069853, COSV101106027; called by muse, mutect2, varscan2
- CELSR1 | c.6262C>T p.R2088* | Nonsense Mutation (SNP) | VAF 43/81 reads (53%) | catalogued as COSV99419456; called by muse, mutect2, varscan2
- CES1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs750790605, COSV100828767; called by muse, mutect2, varscan2
- CLK4 | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100309068; called by muse, mutect2
- DACH2 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913715, COSV100914250; called by muse, mutect2, varscan2
- DCAF8L1 | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs758992618, COSV71595325; called by muse, mutect2, varscan2
- DDX27 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV100874747, COSV65630658; called by muse, mutect2, varscan2
- DISP1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs201957626, COSV99451840; called by muse, mutect2
- DNAH8 | c.2930C>T p.A977V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1060501472, COSV100545777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK4 | c.5717A>G p.Y1906C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1402633409, COSV101447780, COSV101447933; called by muse, mutect2, varscan2
- DSTYK | c.2278G>C p.D760H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100904675; called by muse, mutect2, varscan2
- EP300 | c.4306T>C p.W1436R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54342708, COSV99609154; called by muse, mutect2, varscan2
- F13A1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs138865075; called by muse, mutect2, varscan2
- FCRL2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1295903575, COSV100829979; called by muse, mutect2, varscan2
- FGD5 | c.4115G>A p.R1372Q | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751172332, COSV99548864; called by muse, mutect2, varscan2
- FLNA | c.1568-1G>C p.X523_splice | Splice Site (SNP) | VAF 5/90 reads (6%) | catalogued as COSV61048610; called by muse, mutect2
- FN1 | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as COSV100117888; called by muse, mutect2, varscan2
- GPR15 | c.649T>C p.C217R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99423913; called by muse, mutect2
- HUWE1 | c.5567G>C p.G1856A | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99473679; called by muse, mutect2, varscan2
- IFNW1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.405); catalogued as rs1055776782, COSV66522342; called by muse, mutect2, varscan2
- KANK1 | c.1987A>G p.M663V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs1019104679, COSV100620023; called by muse, mutect2
- KCNA6 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as rs1243961816, COSV54974089; called by muse, mutect2
- KMT2C | c.9235C>T p.R3079* | Nonsense Mutation (SNP) | VAF 79/87 reads (91%) | catalogued as COSV51430355; called by muse, mutect2, varscan2
- LAMA1 | c.8544G>C p.R2848S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV101055594, COSV101057311; called by muse, mutect2, varscan2
- LCE3D | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV100909862, COSV100909869; called by muse, mutect2
- LIMCH1 | c.2233A>G p.N745D | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100574242; called by muse, mutect2, varscan2
- LIX1L | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs587659330, COSV63417133; called by muse, mutect2, varscan2
- LTB4R | c.217T>C p.F73L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1189135105, COSV51866295; called by muse, mutect2
- MYF6 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1234740280, COSV57353681; called by muse, mutect2, varscan2
- MYH2 | c.1438T>C p.C480R | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99820698; called by muse, mutect2
- MYLK | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100659435, COSV60618333; called by muse, mutect2
- NOX1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV54194556; called by muse, mutect2, varscan2
- OR5H2 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100788798; called by muse, mutect2, varscan2
- PCDHGA11 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.532); catalogued as COSV99543999; called by muse, mutect2, varscan2
- PDE8B | c.2344G>A p.V782M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs769655505, COSV99366777; called by muse, mutect2, varscan2
- PIK3C2B | c.3281C>T p.T1094M | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755979604, COSV100916138; called by muse, mutect2, varscan2
- PIWIL1 | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs767074367, COSV99806775; called by muse, mutect2, varscan2
- PLCB3 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs776004312, COSV99657659; called by muse, mutect2, varscan2
- PLD5 | c.326+1G>T p.X109_splice (on ENST00000442594; = p.X47_splice on NM_001195811.1 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 112/196 reads (57%) | catalogued as COSV100142045; called by muse, mutect2, varscan2
- PTPRF | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780147204, COSV63443031, COSV63447137; called by muse, mutect2, varscan2
- RNF25 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs761598782, COSV99829156; called by muse, mutect2, varscan2
- RTBDN | c.563C>T p.A188V (on ENST00000393233 / NM_001270444.1; = p.A220V on NM_031429.2) | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs372483632; called by muse, mutect2, varscan2
- SETD5 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100200982; called by muse, mutect2, varscan2
- SH2D3C | c.587C>T p.S196L (on ENST00000314830 / NM_170600.3; = p.S39L on NM_005489.4) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs769105159, COSV100137288; called by muse, mutect2, varscan2
- SLC33A1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV100848327; called by muse, mutect2, varscan2
- YTHDC2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1284050086, COSV99363722; called by muse, mutect2
- ZNF493 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100828827; called by muse, mutect2, varscan2
- ZNF559 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100416665; called by muse, mutect2, varscan2
- ZNF683 | c.1563C>G p.D521E (on ENST00000403843; = p.D501E on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100853729; called by muse, mutect2, varscan2
- FOXA1 | c.553_555del p.Q185del | In Frame Del (DEL) | VAF 39/83 reads (47%) | called by pindel, varscan2
- MRC1 | c.3445T>A p.S1149T | Missense Mutation (SNP) | VAF 104/261 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RB1 | c.907_908del p.L303Wfs*6 | Frame Shift Del (DEL) | VAF 46/74 reads (62%) | called by pindel, varscan2
- VPS13B | c.11586_11599del p.L3863Sfs*18 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- ABCA1 | c.6345A>G p.A2115= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs764354887, COSV101037465; called by muse, mutect2, varscan2
- ATAD2B | c.273C>T p.R91= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV99478241; called by muse, mutect2, varscan2
- AZGP1 | c.873C>T p.L291= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV99448122; called by muse, mutect2, varscan2
- BTD | c.1344C>T p.F448= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs781065270, COSV100329781; called by muse, varscan2
- CACNA1I | c.5082C>T p.D1694= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs776203223, COSV100360260; called by muse, varscan2
- CTSK | c.858G>A p.Q286= | Silent (SNP) | VAF 73/119 reads (61%) | catalogued as rs1358973920, COSV99648915; called by muse, mutect2, varscan2
- EHBP1 | c.1119T>C p.Y373= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as rs983970906, COSV99861523; called by muse, mutect2, varscan2
- GIMAP8 | c.1326C>T p.V442= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as rs1208225682, COSV100217636; called by muse, mutect2, varscan2
- GTF3C5 | c.225C>T p.C75= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs546891940, COSV59599261; called by muse, mutect2, varscan2
- IL19 | c.321T>C p.I107= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99536404; called by muse, mutect2, varscan2
- ITGA10 | c.507C>A p.V169= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as COSV100994998; called by muse, mutect2, varscan2
- KCNG2 | c.630G>A p.E210= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100302011; called by muse, mutect2, varscan2
- MIER2 | c.432C>T p.D144= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as rs139061333; called by muse, mutect2, varscan2
- NAGS | c.99T>C p.C33= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV99517952; called by muse, mutect2, varscan2
- OR5M1 | c.756T>C p.Y252= | Silent (SNP) | VAF 73/84 reads (87%) | catalogued as rs754181856, COSV101591595; called by muse, mutect2, varscan2
- PAGE3 | c.264T>G p.P88= | Silent (SNP) | VAF 106/267 reads (40%) | catalogued as COSV100892012; called by muse, mutect2, varscan2
- PCDHB3 | c.2322C>T p.F774= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as rs782811619, COSV50566253, COSV50575056; called by muse, mutect2, varscan2
- PLP2 | c.444A>T p.A148= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100889943; called by muse, mutect2, varscan2
- RNF186 | c.249G>A p.P83= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs763077781, COSV100909113; called by muse, mutect2, varscan2
- SEC16A | c.5085C>T p.D1695= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs769186718, COSV99259812; called by muse, mutect2, varscan2
- SEMA4A | c.2106C>T p.L702= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs772147085, COSV61772499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.72876A>G p.T24292= (on ENST00000591111; = p.T16868= on NM_003319.4) | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV100624064; called by muse, mutect2, varscan2
- ZDHHC13 | c.1332A>C p.V444= | Silent (SNP) | VAF 65/76 reads (86%) | catalogued as COSV101240042; called by muse, mutect2, varscan2
- AC073310.1 | n.393T>C | RNA (SNP) | VAF 86/97 reads (89%) | called by muse, mutect2, varscan2
- COG4 | c.-2G>C | 5'UTR (SNP) | VAF 7/113 reads (6%) | catalogued as COSV100092133; called by muse, mutect2
- MAST4 | c.675-49375C>G | Intron (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99845285; called by muse, mutect2, varscan2
- VMP1 | c.*1423_*1427del | 3'UTR (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
